Gene-level copy-number profile of tumor specimen TCGA-LN-A5U6-01A from TCGA case TCGA-LN-A5U6, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 54.3 years (19,840 days).
Specimen TCGA-LN-A5U6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.83e08d7a-85e3-4f25-8ccb-4233799e57f9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A5U6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/46d5ace1-e011-4951-8730-31aa6bf155ef

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 122; copy number 1: 7,012; copy number 2: 23,459; copy number 3: 22,397; copy number 4: 3,502; copy number 5: 1,821; copy number 6: 204; copy number 7: 148; copy number 8: 350; copy number 9: 329; copy number 10: 226; copy number 11: 105; copy number 12: 25; copy number 13: 110.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LN-A5U6-01A-11D-A28A-01): tumor purity 0.72, ploidy 2.68, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 117 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:21,697,450–21,853,188, 2 genes: AC096576.2, KCNIP4-IT1.
- chr4:37,699,895–37,700,002, 1 gene: Y_RNA.
- chr6:91,521,660–94,194,658, 24 genes: MIR4643, CASC6, MTATP6P25, MTND4LP19, MTCO1P56, RN7SL415P, AL590635.1, AL590814.1, RPL5P19, U3, AL133457.1, AL359987.1, LINC02531, U3, ATF1P1, AL138731.1, COPS5P1, EPHA7, AL591519.1, AL356094.2, AL356094.1, AL391336.2, AL391336.1, AL157378.1.
- chr9:21,524,307–28,670,286, 72 genes (within-gene range 0–5) (broad region; genes not listed).
- chr15:59,105,126–59,133,250, 3 genes: CCNB2, AC092757.3, AC092757.2.
- chr15:59,171,183–59,212,788, 3 genes: MIR2116, LDHAL6B, RNU4-80P.
- chr18:80,147,924–80,247,514, 4 genes (within-gene range 0–1): PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.
- chr19:7,011,884–7,294,414, 8 genes (within-gene range 0–2): AC025278.3, MBD3L2B, MBD3L5, MBD3L4, MBD3L2, MBD3L3, ZNF557, INSR.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,314 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:115,700,021–118,615,646, 57 genes, copy number 5 (within-gene range 1–5): CASQ2, NHLH2, HNRNPA1P43, LINC01649, AL357137.1, SLC22A15, AL365318.1, MAB21L3, LINC01779, U3, AL355538.1, ATP1A1, ATP1A1-AS1, RNU6-817P, LINC01762, AL136376.1, Y_RNA, AL390066.1, AL390066.2, CD58, NAP1L4P1, MIR548AC, IGSF3, MIR320B1, LINC02868, GAPDHP64, NEFHP1, CD2, FTH1P22, AL157904.1, PTGFRN, RNA5SP55, CD101, AL445231.1, TTF2, MIR942, TRIM45, RPS15AP9, VTCN1, Metazoa_SRP, LINC01525, AL358072.1, MAN1A2, AL157902.2, VPS25P1, AL157902.1, TENT5C, VDAC2P3, AL390877.1, AL390877.2, PNRC2P1, GDAP2, WDR3, SPAG17, AL391557.1, RNA5SP56, PSMC1P12.
- chr2:78,597,911–80,648,861, 20 genes, copy number 5–8 (within-gene range 3–8): AC092660.1, AC092604.1, RNU6-827P, RNU6-812P, REG3G, REG1B, REG1A, REG1CP, REG3A, AC011754.1, CTNNA2, AC011754.2, CTNNA2-AS1, AC010975.1, GNA13P1, RNU6-561P, MIR4264, MIR8080, AC016716.1, RBM7P1.
- chr2:105,600,703–106,208,115, 9 genes, copy number 5–8 (within-gene range 4–8): AC018802.1, AC018802.2, NCK2, AC010978.1, AC009505.1, ECRG4, UXS1, AC018878.1, AC092106.1.
- chr2:117,180,892–121,649,476, 61 genes, copy number 6–10 (within-gene range 3–10) (broad region; genes not listed).
- chr2:170,601,662–173,576,341, 56 genes, copy number 9–11: HMGB1P4, AC007277.1, AC007277.2, AC007405.1, LINC01124, SP5, EIF2S2P4, AC007405.3, Y_RNA, ERICH2, GAD1, AC007405.2, AC007405.4, AC010092.1, GORASP2, TLK1, METTL8, RPS26P20, DCAF17, DAP3P2, AC007969.1, RPS15P4, CYBRD1, RPL21P38, DYNC1I2, SLC25A12, RNU6-182P, HAT1, METAP1D, DLX1, DLX2, DLX2-DT, AC104088.1, AC104088.3, AC104088.2, AC078883.3, ITGA6, AC078883.2, ITGA6-AS1, AC078883.1, PDK1, Y_RNA, AC018712.1, RAPGEF4-AS1, AC018712.2, RAPGEF4, ALDH7A1P2, MAP3K20, MAP3K20-AS1, RPS2P18, AC092573.1, CDCA7, JPT1P1, CBY1P1, PPIAP66, AC013410.1.
- chr2:175,072,250–175,168,382, 1 gene, copy number 7 (within-gene range 4–7): ATF2.
- chr2:175,167,633–178,402,893, 79 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr2:186,827,475–188,595,931, 14 genes, copy number 6 (within-gene range 3–6): ZSWIM2, IMPDH1P7, AC007319.1, RN7SKP42, RNU6-989P, CALCRL, GAPDHP59, TFPI, LINC01090, ST13P2, AC104131.1, RNA5SP114, GULP1, MIR561.
- chr3:134,597,801–135,260,467, 1 gene, copy number 7 (within-gene range 3–7): EPHB1.
- chr3:134,774,543–134,796,493, 3 genes, copy number 7: AC016931.1, RNU6-1174P, RNA5SP141.
- chr3:149,129,638–198,222,513, 883 genes, copy number 8–13 (broad region; genes not listed).
- chr4:129,771,596–130,504,344, 5 genes, copy number 5: LINC02465, EEF1GP8, LINC02479, PGBD4P4, GAPDHP56.
- chr5:58,198–32,110,932, 481 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr5:44,808,947–45,895,970, 8 genes, copy number 7–8: MRPS30, AC093297.2, AC114954.1, AC116350.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr6:57,961,438–58,438,364, 1 gene, copy number 6 (within-gene range 1–6): AL445250.1.
- chr6:58,386,799–58,386,961, 1 gene, copy number 6: AL603755.1.
- chr6:66,710,242–66,728,904, 2 genes, copy number 5: AL450336.1, RNU7-66P.
- chr6:81,491,439–82,367,420, 15 genes, copy number 7–9: TENT5A, AL122017.1, AL359693.1, RNA5SP210, AL078599.2, SNORA70, AL078599.1, LINC01526, LINC02542, AL360157.1, IBTK, RNU6-130P, AL121977.1, AL121977.2, TPBG.
- chr7:77,038–81,178, 1 gene, copy number 5: AC093627.6.
- chr8:110,609,241–118,982,875, 54 genes, copy number 5: AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, AC022360.1, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC055788.1, AC103993.1, Y_RNA, AC064802.1, AC025881.1, CARS1P2, TRPS1, AF178030.1, LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16, EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1.
- chr9:28,539,735–29,318,952, 7 genes, copy number 5: AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1.
- chr10:2,936,021–5,107,686, 44 genes, copy number 5–6: AC026396.1, AL731533.1, AL731533.3, AL731533.2, PFKP, AL451164.2, PITRM1, PITRM1-AS1, AL451164.3, AL451164.1, LINC02668, AL139280.1, AL139280.3, AL139280.2, AL356433.1, LINC02669, AL357833.1, AL450322.2, AL450322.1, KLF6, AL513303.1, LINC02639, LINC02660, MIR6078, AC025822.1, AC025822.2, LINC00702, LINC00703, AC022535.1, AC022535.3, AC022535.2, RNU6-163P, MANCR, LINC00705, AC018978.1, AKR1E2, AKR1C6P, U8, AKR1C1, AKR1C2, AL391427.1, U8, AKR1C3, U8.
- chr11:48,880,111–54,725,816, 68 genes, copy number 5 (broad region; genes not listed).
- chr11:69,294,151–72,434,680, 110 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr14:46,839,629–63,544,664, 317 genes, copy number 5–10 (broad region; genes not listed).
- chr18:23,004,564–49,461,347, 345 genes, copy number 5–8 (within-gene range 1–8) (broad region; genes not listed).
- chr19:3,224,661–3,928,082, 34 genes, copy number 5 (within-gene range 1–5): CELF5, AC010649.1, NFIC, AC007792.1, AC005514.1, SMIM24, AC005551.1, DOHH, FZR1, AC005787.1, MFSD12, C19orf71, AC005786.3, AC005786.2, AC005786.4, AC005786.1, HMG20B, GIPC3, TBXA2R, CACTIN-AS1, CACTIN, PIP5K1C, AC004637.1, TJP3, APBA3, AC005954.2, AC005954.1, MRPL54, RAX2, AC005777.1, MATK, ZFR2, FTLP5, ATCAY.
- chr20:87,250–30,403,384, 567 genes, copy number 5–6 (broad region; genes not listed).
- chr22:49,612,657–50,801,309, 70 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,727. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
